Somatic mutation profile of tumor specimen TCGA-19-4065-01A (aliquot TCGA-19-4065-01A-01D-2280-08) from TCGA case TCGA-19-4065, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 36.3 years (13,257 days).
Specimen TCGA-19-4065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 097d139f-b9bb-4ae1-a50f-1749c573efa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-4065-10A (Blood Derived Normal), aliquot TCGA-19-4065-10A-01D-2280-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a53c752a-f6b8-4e0c-993f-732b9128bf50

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 16, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH6 | c.4369G>A p.E1457K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs267606905, CM052259, COSV100676195, COSV100676755; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.81T>G p.Y27* | Nonsense Mutation (SNP) | VAF 15/24 reads (63%) | hotspot (GDC flag); catalogued as CM128488, COSV64291164, COSV64310374; called by muse, varscan2
- TP53 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 48/90 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs587782705, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.2356T>C p.S786P | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99535768; called by muse, mutect2, varscan2
- AHCY | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); catalogued as rs1391812572, COSV99463917; called by muse, mutect2, varscan2
- COL2A1 | c.2563G>A p.G855S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193507525, COSV100475237; called by muse, mutect2, varscan2
- COL5A1 | c.2723C>T p.P908L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs772211736, COSV65678216; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPD | c.3383A>G p.N1128S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs1252229931, COSV99852356; called by muse, mutect2, varscan2
- CSNK1G3 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV100631287; called by muse, mutect2
- DNAH3 | c.1527G>T p.W509C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.63); catalogued as COSV54524775; called by muse, mutect2, varscan2
- FAM91A1 | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs754338365, COSV100593440, COSV58235865; called by muse, mutect2, varscan2
- FLYWCH1 | c.1357C>T p.R453W (on ENST00000253928 / NM_001308068.2; = p.R452W on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1313670616, COSV99558403; called by muse, mutect2
- FRMD7 | c.2032C>T p.R678C | Missense Mutation (SNP) | VAF 44/63 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1213344421, COSV53748805; called by muse, mutect2, varscan2
- IGHV3-73 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs184224767; called by muse, mutect2
- KIAA0100 | c.6370C>T p.P2124S | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV99971883; called by muse, mutect2, varscan2
- KIF2B | c.697C>A p.L233M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99274508; called by muse, mutect2, varscan2
- KRT31 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1424045088, COSV99289312; called by muse, mutect2, varscan2
- MATK | c.1357G>A p.V453M (on ENST00000310132 / NM_139355.3; = p.V454M on NM_002378.4) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs756287133, COSV100035761, COSV59553131, COSV59556917; called by muse, mutect2, varscan2
- MYO15A | c.628G>T p.D210Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.891); catalogued as COSV99230779; called by muse, mutect2
- NCKAP1L | c.3341G>A p.R1114Q | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs867197350, COSV53203951; called by muse, mutect2, varscan2
- NETO1 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172565808, COSV100198073; called by muse, mutect2, varscan2
- OBSCN | c.7714G>A p.E2572K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.636); catalogued as COSV99471285; called by muse, mutect2, varscan2
- OR2W3 | c.816G>T p.M272I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100831575; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.188A>T p.E63V (on ENST00000374531 / NM_001037293.2; = p.E61V on NM_007203.5) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100092406; called by muse, mutect2, varscan2
- PEG10 | c.158A>G p.E53G (on ENST00000482108 / NM_001040152.2; = p.E87G on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV101509839; called by muse, mutect2, varscan2
- PHKA1 | c.883C>T p.R295C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262345; called by muse, mutect2, varscan2
- PIK3CG | c.1869T>A p.D623E | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.173); catalogued as COSV100782443; called by muse, mutect2, varscan2
- POLRMT | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs576840960, COSV101648653; called by muse, mutect2, varscan2
- RXFP1 | c.2204C>T p.P735L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as rs778516371, COSV100313488; called by muse, mutect2, varscan2
- RYR2 | c.1576T>C p.W526R | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100767311; called by muse, mutect2, varscan2
- SBK1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1364511498, COSV100543364; called by muse, mutect2
- SEMA3C | c.681T>A p.H227Q | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV99543051; called by muse, mutect2
- SLC30A3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs759566076, COSV51984503; called by muse, mutect2, varscan2
- SLC5A7 | c.1447G>T p.A483S | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV99886117; called by muse, mutect2, varscan2
- THSD7B | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs568467115, COSV55677825; called by muse, mutect2, varscan2
- ABCA5 | c.2167_2168del p.L723Ffs*5 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- C12orf50 | c.987G>A p.A329= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as rs762685869, COSV100072284, COSV53894688; called by muse, mutect2, varscan2
- DNAH3 | c.4047C>T p.D1349= | Silent (SNP) | VAF 72/180 reads (40%) | catalogued as rs774286374, COSV54525528; called by muse, mutect2, varscan2
- EPPK1 | c.2997C>A p.G999= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV101599715; called by muse, mutect2, varscan2
- FLT4 | c.1797C>T p.H599= | Silent (SNP) | VAF 17/93 reads (18%) | catalogued as rs200474566, COSV56100158; called by muse, mutect2, varscan2
- LRFN2 | c.663C>G p.S221= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100599043; called by muse, mutect2, varscan2
- MAGEB6 | c.777C>T p.G259= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as rs765918379, COSV100983642; called by muse, mutect2, varscan2
- OR52B6 | c.390C>T p.H130= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV100798461; called by muse, mutect2, varscan2
- PPP4R4 | c.2280G>A p.S760= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs367998986; called by muse, mutect2, varscan2
- RIOX2 | c.666T>C p.H222= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as rs1044688829, COSV100328081; called by muse, mutect2, varscan2
- SHANK1 | c.2586C>T p.F862= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1216154072, COSV53243998; called by muse, mutect2
- SLC9A4 | c.915C>T p.I305= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV54838915; called by muse, mutect2, varscan2
- ST3GAL6 | c.234C>T p.S78= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as rs143638537; called by muse, mutect2, varscan2
- STYXL2 | c.2010C>T p.S670= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs200893444; called by muse, mutect2, varscan2
- TRANK1 | c.1980T>C p.P660= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV100081068; called by muse, mutect2
- USH2A | c.195T>C p.T65= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV56450990; called by muse, mutect2, varscan2
- ZNF462 | c.4587C>T p.G1529= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs373087468; called by muse, mutect2, varscan2
- DCHS2 | n.4556T>C | RNA (SNP) | VAF 14/134 reads (10%) | catalogued as COSV100600923; called by muse, mutect2, varscan2
